Somatic mutation profile of tumor specimen TCGA-CX-7082-01A (aliquot TCGA-CX-7082-01A-11D-2012-08) from TCGA case TCGA-CX-7082, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 82.6 years (30,174 days).
Specimen TCGA-CX-7082-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 758fddcc-7ec6-4b07-866f-3ddcd37813d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CX-7082-10A (Blood Derived Normal), aliquot TCGA-CX-7082-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5fbf430-3ee4-43a1-894c-dfa0d596e8fd

The open-access MAF lists 99 somatic variants for this specimen: 74 protein-altering or splice-affecting, 24 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 24, Nonsense Mutation 6, Frame Shift Del 3, Frame Shift Ins 2, Splice Region 1, Nonstop Mutation 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 27/41 reads (66%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABHD18 | c.1229A>T p.Q410L (on ENST00000398965 / NM_001039717.2; = p.Q317L on NM_025097.2 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs1357211635, COSV101180894; called by muse, mutect2, varscan2
- AGAP2 | c.2201A>C p.K734T (on ENST00000547588 / NM_001122772.2; = p.K398T on NM_014770.4) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99224326; called by muse, mutect2
- AJUBA | c.1078C>T p.H360Y | Missense Mutation (SNP) | VAF 84/110 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99401205; called by muse, mutect2, varscan2
- ALK | c.2431G>T p.V811L | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.173); catalogued as COSV101202750, COSV66560705; called by muse, mutect2, varscan2
- C5orf34 | c.670C>G p.L224V | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT tolerated (0.9); PolyPhen benign (0.099); catalogued as COSV100175610; called by muse, mutect2, varscan2
- CCDC88B | c.2678G>T p.R893L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as COSV100105961, COSV57266823; called by muse, varscan2
- CCNE2 | c.608A>G p.Y203C | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as COSV100353894; called by muse, mutect2, varscan2
- CDKN2AIP | c.1307A>G p.K436R | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV100187742; called by muse, mutect2, varscan2
- CENPT | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.276); catalogued as COSV99535361; called by muse, mutect2, varscan2
- COL11A1 | c.5052A>T p.L1684F | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as COSV100618095; called by muse, mutect2, varscan2
- COL15A1 | c.3176G>A p.G1059E | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100898010; called by muse, mutect2, varscan2
- DCAF6 | c.1346A>T p.E449V | Missense Mutation (SNP) | VAF 39/54 reads (72%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV100394897; called by muse, mutect2, varscan2
- DNAH10 | c.1258G>A p.V420M (on ENST00000409039; = p.V359M on NM_207437.3) | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.265); catalogued as rs1403614920, COSV68990676; called by muse, mutect2, varscan2
- DOCK10 | c.5314A>T p.M1772L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV99291742; called by muse, mutect2
- EPS15L1 | c.1431C>G p.I477M | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV50170923; called by muse, varscan2
- FAT1 | c.7151A>G p.N2384S | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as rs139480903, COSV101499656; called by muse, mutect2, varscan2
- GRAMD1C | c.1922T>G p.L641R | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV100362262, COSV57630062; called by muse, varscan2
- GRIP1 | c.373G>T p.G125* | Nonsense Mutation (SNP) | VAF 46/140 reads (33%) | catalogued as COSV99671107; called by muse, mutect2, varscan2
- GTPBP4 | c.196C>G p.L66V | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.142); catalogued as COSV100672943, COSV62550902; called by muse, mutect2, varscan2
- HRG | c.1117G>T p.E373* | Nonsense Mutation (SNP) | VAF 28/37 reads (76%) | catalogued as COSV99215088, COSV99215163; called by muse, mutect2, varscan2
- KALRN | c.4724T>A p.I1575N | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99567440; called by muse, mutect2, varscan2
- KCNS3 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs1398464477, COSV58409222; called by muse, mutect2, varscan2
- KRT86 | c.1129A>G p.K377E | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99525115; called by muse, mutect2, varscan2
- LNPK | c.1249G>T p.D417Y | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.188); catalogued as COSV55824546, COSV99770484; called by muse, varscan2
- LNPK | c.1202C>T p.S401L | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99770242, COSV99770486; called by muse, varscan2
- LYST | c.10417G>A p.V3473M | Missense Mutation (SNP) | VAF 56/69 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs754218446, COSV101089245; called by muse, mutect2, varscan2
- M1AP | c.991A>T p.R331* | Nonsense Mutation (SNP) | VAF 42/112 reads (38%) | catalogued as COSV99304530; called by muse, mutect2, varscan2
- MACC1 | c.1879G>A p.D627N | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV100256311; called by muse, mutect2, varscan2
- MAML2 | c.2135G>C p.R712T | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.1); PolyPhen benign (0.186); catalogued as COSV101594200; called by muse, mutect2, varscan2
- MDGA2 | c.2308A>T p.T770S (on ENST00000399232 / NM_001113498.2; = p.T472S on NM_182830.4) | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0.247); catalogued as COSV100638545; called by muse, mutect2, varscan2
- MIIP | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.105); catalogued as COSV99337797; called by muse, mutect2, varscan2
- NXPH3 | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 6/89 reads (7%) | catalogued as COSV100165592; called by muse, mutect2
- OLFM4 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99524585; called by muse, mutect2, varscan2
- OR1L4 | c.233T>C p.I78T | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1249222284, COSV99413963; called by muse, mutect2, varscan2
- OSBPL11 | c.1418T>C p.F473S | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99954532; called by muse, mutect2, varscan2
- OXSM | c.107C>A p.P36Q | Missense Mutation (SNP) | VAF 47/82 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99772141; called by muse, mutect2, varscan2
- P4HB | c.1283C>A p.T428N | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100515930; called by muse, varscan2
- PDGFD | c.1111T>A p.*371Kext*16 | Nonstop Mutation (SNP) | VAF 11/82 reads (13%) | catalogued as COSV100160961; called by muse, mutect2, varscan2
- PIK3CA | c.983G>C p.W328S | Missense Mutation (SNP) | VAF 29/382 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as rs1235701540, COSV99844012; called by muse, mutect2
- PLSCR1 | c.90C>G p.F30L | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV100678467; called by muse, mutect2, varscan2
- PLXNB2 | c.4972T>C p.F1658L | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100834331; called by muse, mutect2, varscan2
- PRH1 | c.461G>A p.G154D | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs762959146, COSV101457513; called by muse, mutect2, varscan2
- PTPRB | c.1249G>T p.V417L | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV99719068; called by muse, mutect2, varscan2
- PZP | c.3667C>A p.L1223I | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99739544; called by muse, mutect2, varscan2
- RBM41 | c.361C>G p.L121V | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV99179839; called by muse, mutect2, varscan2
- RTN4IP1 | c.1030A>G p.M344V | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.049); catalogued as rs768014057, COSV100954242; called by muse, mutect2, varscan2
- RTTN | c.1465C>T p.P489S | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99733911; called by muse, mutect2, varscan2
- RWDD3 | c.425C>G p.T142S | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.084); catalogued as COSV99811735; called by muse, mutect2, varscan2
- SAMD11 | c.303C>T p.C101= | Splice Region (SNP) | VAF 22/57 reads (39%) | catalogued as COSV100574715; called by muse, mutect2, varscan2
- SERPIND1 | c.1055dup p.I353Hfs*67 | Frame Shift Ins (INS) | VAF 32/108 reads (30%) | catalogued as rs1569029107; called by mutect2, pindel, varscan2
- SGPL1 | c.235A>T p.R79W | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100167351; called by muse, mutect2, varscan2
- SH3RF3 | c.1022T>G p.L341R | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.467); catalogued as COSV100513883; called by muse, mutect2
- SLC16A13 | c.487C>T p.L163F | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as rs760446782, COSV100338765; called by muse, mutect2, varscan2
- SLC2A6 | c.1153C>T p.Q385* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as COSV99390455; called by muse, mutect2, varscan2
- SLC4A2 | c.3016A>G p.I1006V | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99879994; called by muse, mutect2, varscan2
- SMC3 | c.3579T>A p.N1193K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100700060; called by muse, varscan2
- SMURF1 | c.1540T>C p.F514L | Missense Mutation (SNP) | VAF 67/124 reads (54%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.879); catalogued as COSV100705412; called by muse, mutect2, varscan2
- SS18 | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.73); catalogued as COSV99294142, COSV99294450; called by muse, mutect2, varscan2
- SURF2 | c.648_649del p.E216Dfs*37 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | catalogued as rs782642385; called by pindel, varscan2
- TAF2 | c.966G>C p.M322I | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as COSV100978818; called by muse, varscan2
- THAP6 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.192); catalogued as COSV100185988; called by muse, mutect2, varscan2
- TMLHE | c.959A>G p.N320S | Missense Mutation (SNP) | VAF 71/86 reads (83%) | SIFT tolerated (0.23); PolyPhen benign (0.112); catalogued as COSV100545119; called by muse, mutect2, varscan2
- TRHR | c.557A>T p.N186I | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as COSV100305122; called by muse, mutect2, varscan2
- UQCRFS1 | c.808A>G p.M270V | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100508186; called by muse, mutect2, varscan2
- USP48 | c.2594A>T p.Y865F | Missense Mutation (SNP) | VAF 71/206 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV100380268; called by muse, mutect2, varscan2
- VSIG2 | c.722G>C p.R241P | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV52517777, COSV52517790; called by muse, mutect2, varscan2
- XPOT | c.2635C>G p.L879V | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV100225768; called by muse, mutect2, varscan2
- ZNF107 | c.82A>G p.K28E | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.057); catalogued as COSV100788538; called by muse, mutect2, varscan2
- ZNF507 | c.1153A>G p.I385V | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100322137; called by muse, mutect2, varscan2
- CEP170 | c.1036_1040del p.L346Gfs*8 | Frame Shift Del (DEL) | VAF 15/25 reads (60%) | called by mutect2, varscan2
- CPT2 | c.973del p.L325Sfs*3 | Frame Shift Del (DEL) | VAF 23/76 reads (30%) | called by mutect2, pindel, varscan2
- HEXA | c.254-28_254del p.X85_splice | Splice Site (DEL) | VAF 13/45 reads (29%) | called by mutect2, pindel
- MEI1 | c.3651dup p.G1218Wfs*14 | Frame Shift Ins (INS) | VAF 19/60 reads (32%) | called by mutect2, pindel, varscan2
- BCL9 | c.4260C>T p.N1420= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as rs781937794, COSV99325874; called by muse, mutect2, varscan2
- COLEC11 | c.531G>T p.L177= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV99363706; called by muse, mutect2, varscan2
- DISP1 | c.4455A>G p.R1485= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV99452240; called by muse, mutect2, varscan2
- EPRS1 | c.306C>G p.L102= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as rs1419373682, COSV100859516; called by muse, mutect2, varscan2
- HSPA1A | c.1821C>T p.I607= | Silent (SNP) | VAF 34/123 reads (28%) | catalogued as rs1182891361, COSV100989460, COSV65148779; called by muse, mutect2, varscan2
- IL11RA | c.138G>A p.L46= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV100535460; called by muse, mutect2, varscan2
- KRTAP26-1 | c.300T>C p.A100= | Silent (SNP) | VAF 25/100 reads (25%) | catalogued as COSV100860489; called by muse, mutect2, varscan2
- LRRTM1 | c.1158C>A p.P386= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV54446637; called by muse, mutect2, varscan2
- MORC2 | c.2046C>G p.V682= (on ENST00000397641 / NM_001303256.3; = p.V620= on NM_014941.3) | Silent (SNP) | VAF 31/92 reads (34%) | catalogued as COSV99310462; called by muse, mutect2, varscan2
- MUC16 | c.35223G>A p.E11741= | Silent (SNP) | VAF 44/97 reads (45%) | catalogued as COSV101201809; called by muse, mutect2, varscan2
- NEMP1 | c.856C>T p.L286= (on ENST00000300128 / NM_001130963.2; = p.L213= on NM_015257.3) | Silent (SNP) | VAF 53/135 reads (39%) | catalogued as rs148717635; called by muse, mutect2, varscan2
- OR10Q1 | c.831C>T p.S277= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as COSV100372407; called by muse, mutect2, varscan2
- PCDHB4 | c.1209A>T p.V403= | Silent (SNP) | VAF 32/51 reads (63%) | catalogued as COSV99522519; called by muse, mutect2, varscan2
- PTGFRN | c.297C>T p.N99= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV67798431; called by mutect2, varscan2
- SHANK3 | c.366C>T p.Y122= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs540912813, COSV99438051; called by muse, mutect2, varscan2
- SLC47A2 | c.1515A>C p.S505= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV99450299; called by muse, mutect2, varscan2
- SMURF1 | c.1152C>T p.V384= | Silent (SNP) | VAF 128/228 reads (56%) | catalogued as COSV100742635; called by muse, mutect2, varscan2
- STT3A | c.1098C>T p.L366= | Silent (SNP) | VAF 40/73 reads (55%) | catalogued as COSV101205290; called by muse, mutect2, varscan2
- TMEFF2 | c.369G>A p.Q123= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV99772493; called by muse, mutect2, varscan2
- USP1 | c.273T>C p.Y91= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as COSV100375467; called by muse, mutect2, varscan2
- ZBTB37 | c.12T>C p.G4= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV100774654; called by muse, mutect2
- ZNF225 | c.1404C>T p.A468= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as COSV99489618; called by muse, mutect2, varscan2
- ZNF233 | c.942T>C p.Y314= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as rs768613329, COSV100492482; called by muse, mutect2, varscan2
- ZNF366 | c.861G>C p.G287= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as COSV100574199, COSV100574514; called by muse, mutect2, varscan2
- AC024940.1 | n.2245del | RNA (DEL) | VAF 8/22 reads (36%) | called by mutect2, pindel, varscan2
